Somatic mutation profile of tumor specimen TCGA-CV-A6JU-01A (aliquot TCGA-CV-A6JU-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JU, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 61.9 years (22,591 days).
Specimen TCGA-CV-A6JU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05fd2ae5-7e7e-4e40-8080-9e098d4a3af1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JU-10A (Blood Derived Normal), aliquot TCGA-CV-A6JU-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f6168c7-1cbb-40cd-977d-870a641bbb88

The open-access MAF lists 142 somatic variants for this specimen: 102 protein-altering or splice-affecting, 33 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 33, Frame Shift Ins 10, Nonsense Mutation 5, Splice Site 4, Intron 3, In Frame Del 2, Frame Shift Del 2, RNA 2, Splice Region 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.672+1G>T p.X224_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- TP63 | c.580-1G>T p.X194_splice | Splice Site (SNP) | VAF 101/289 reads (35%) | hotspot (GDC flag); catalogued as COSV53205039, COSV99285668; called by muse, mutect2, varscan2
- ABCC8 | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV100217354; called by muse, mutect2, varscan2
- ADAR | c.2693C>G p.S898C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52711774, COSV52718619; called by muse, mutect2, varscan2
- ADCY5 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV101518440; called by muse, mutect2
- ALCAM | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100064946; called by muse, mutect2
- ARHGEF4 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV100388261; called by muse, mutect2, varscan2
- ASTN1 | c.1467G>C p.M489I | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.679); catalogued as COSV99922033; called by muse, mutect2, varscan2
- ATP10A | c.2356G>C p.G786R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as rs960580954, COSV100791318; called by muse, mutect2, varscan2
- ATXN2 | c.3619C>T p.P1207S (on ENST00000550104; = p.P1047S on NM_002973.4) | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372267174; called by muse, mutect2, varscan2
- BCO2 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100730379; called by muse, mutect2, varscan2
- BPIFB2 | c.1320G>T p.E440D | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.422); catalogued as COSV99401454; called by muse, mutect2, varscan2
- C3 | c.2427G>A p.M809I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99836783; called by muse, mutect2, varscan2
- CAMSAP2 | c.1841C>G p.T614S (on ENST00000236925 / NM_001297707.2; = p.T603S on NM_203459.3) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.135); catalogued as COSV99373511; called by muse, mutect2, varscan2
- CDH16 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV55339764; called by muse, mutect2, varscan2
- CFAP46 | c.7566G>T p.E2522D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV54150824, COSV54157247; called by muse, mutect2
- CFAP69 | c.1182G>C p.L394F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV60186053; called by muse, mutect2, varscan2
- CHST8 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as rs761058926, COSV52858907, COSV52862302; called by muse, mutect2, varscan2
- CIT | c.945_947del p.I315del | In Frame Del (DEL) | VAF 15/91 reads (16%) | catalogued as rs758752899; called by mutect2, pindel, varscan2
- CNTN3 | c.2078T>A p.V693E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV99724811; called by muse, mutect2, varscan2
- COL23A1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101179029; called by muse, mutect2, varscan2
- CPNE4 | c.1277A>T p.E426V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV101456736; called by muse, mutect2, varscan2
- CPXM1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101013755; called by muse, mutect2, varscan2
- CSH1 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs17854931, COSV100298362; called by muse, mutect2, varscan2
- CSMD3 | c.11113A>C p.T3705P (on ENST00000297405 / NM_001363185.1; = p.T3536P on NM_052900.3) | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99836715; called by muse, mutect2, varscan2
- CT45A10 | c.389T>A p.V130E | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV100867538; called by muse, mutect2, varscan2
- DAGLA | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99944457; called by muse, mutect2, varscan2
- DCX | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100576509, COSV57576626; called by muse, mutect2, varscan2
- DNAH8 | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100545783; called by muse, mutect2, varscan2
- DNAH8 | c.11846G>C p.R3949P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545784, COSV59426779; called by muse, mutect2, varscan2
- DYNC1H1 | c.5024G>C p.G1675A | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.638); catalogued as COSV100795014; called by muse, mutect2, varscan2
- ENOX1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as COSV99816229; called by muse, mutect2, varscan2
- FAT1 | c.10195G>T p.D3399Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499398, COSV71673568; called by muse, mutect2, varscan2
- FAT3 | c.4583C>T p.A1528V | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV99966969; called by muse, mutect2, varscan2
- FGD6 | c.1825A>G p.M609V | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779820448, COSV100676645; called by muse, mutect2, varscan2
- FTHL17 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100784315, COSV63266751; called by muse, mutect2, varscan2
- GABRA1 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV50121094, COSV99195974; called by muse, mutect2, varscan2
- GABRR1 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as COSV101033951; called by muse, mutect2, varscan2
- GATA3 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100651049, COSV60523751; called by muse, mutect2, varscan2
- GRIN2B | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs1555119408, COSV74207148, COSV74208531; called by muse, mutect2, varscan2
- H2AC15 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs142211266, COSV100357002; called by muse, mutect2, varscan2
- HRNR | c.2091G>C p.Q697H | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1244296014, COSV100913564; called by muse, mutect2, varscan2
- HYAL3 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100269563; called by muse, mutect2, varscan2
- IGHG4 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as rs1290729648; called by muse, mutect2
- INPP4A | c.1895C>A p.P632Q (on ENST00000074304 / NM_001134224.1; = p.P593Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99303383, COSV99304207; called by muse, mutect2, varscan2
- KRT12 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770184655, COSV52429589; called by muse, mutect2, varscan2
- KRT26 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV100156532; called by muse, mutect2, varscan2
- KRT86 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs762794979, COSV53292291; called by muse, mutect2, varscan2
- LAMB2 | c.4816A>G p.T1606A | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100026239; called by muse, mutect2, varscan2
- LDB3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 84/376 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs544084461, COSV53950265; called by muse, mutect2, varscan2
- LILRB4 | c.276T>G p.Y92* | Nonsense Mutation (SNP) | VAF 37/263 reads (14%) | catalogued as COSV99553866; called by muse, varscan2
- MYH13 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99354285; called by muse, mutect2, varscan2
- MYL4 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100733132; called by muse, mutect2, varscan2
- MYO5A | c.2270A>T p.Y757F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100697759; called by muse, mutect2, varscan2
- NAGA | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs545476351, COSV67170065; called by muse, mutect2
- NEXN | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99628975; called by muse, mutect2
- NLRP3 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100276193; called by muse, mutect2
- OCA2 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100668061; called by muse, mutect2, varscan2
- OR10S1 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs748991297, COSV101602483, COSV73342652, COSV73342905; called by muse, mutect2, varscan2
- OR2T33 | c.901C>G p.R301G | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100531985; called by muse, mutect2, varscan2
- OSBPL9 | c.144A>T p.R48S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100543532; called by muse, mutect2, varscan2
- P4HA2 | c.1372-1G>T p.X458_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99387107; called by muse, mutect2, varscan2
- PCLO | c.3335A>T p.Q1112L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100433535; called by muse, mutect2, varscan2
- PDK4 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99138852; called by muse, mutect2, varscan2
- PGPEP1 | c.207G>C p.L69= | Splice Region (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99416603; called by muse, mutect2, varscan2
- PTPRD | c.1039A>G p.N347D | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.734); catalogued as COSV100645137; called by muse, mutect2, varscan2
- PTPRH | c.1964C>A p.S655Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.18); catalogued as COSV99671105; called by muse, mutect2, varscan2
- RBCK1 | c.244G>A p.A82T (on ENST00000356286 / NM_031229.4; = p.A40T on NM_006462.6) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as rs907585079, COSV100675853; called by muse, mutect2, varscan2
- RGS7 | c.1078T>A p.L360I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.812); catalogued as COSV100468199, COSV58532254; called by muse, mutect2, varscan2
- RUFY2 | c.1142C>G p.T381S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV99769306; called by muse, mutect2, varscan2
- SEMA3E | c.253A>T p.R85* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100318789; called by muse, mutect2, varscan2
- SEMA6D | c.1940G>A p.R647Q (on ENST00000316364 / NM_153618.2; = p.R585Q on NM_020858.2) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.233); catalogued as rs775757768, COSV100317124, COSV99054636; called by muse, mutect2, varscan2
- SLC10A6 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99907291; called by muse, mutect2, varscan2
- SPEM2 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1331721062, COSV100424354; called by muse, mutect2, varscan2
- SPTAN1 | c.1326G>T p.L442= | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100823652; called by muse, mutect2, varscan2
- SSTR1 | c.923C>G p.S308W | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99942926; called by muse, mutect2, varscan2
- SVIL | c.3067A>G p.M1023V (on ENST00000355867 / NM_021738.3; = p.M597V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100881316; called by muse, mutect2, varscan2
- TDRD1 | c.2395G>T p.D799Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52598902; called by muse, mutect2, varscan2
- TEKT1 | c.472T>A p.S158T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100106245; called by muse, mutect2, varscan2
- TMEM201 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV100440470; called by muse, mutect2, varscan2
- TMEM35A | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99515491; called by muse, mutect2, varscan2
- TNFRSF11A | c.1580G>C p.G527A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99500224, COSV99500285; called by muse, mutect2
- UNC13C | c.3001G>T p.E1001* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV52859270; called by muse, mutect2, varscan2
- USP11 | c.1697G>A p.R566H (on ENST00000218348; = p.R523H on NM_001371072.1) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99510981; called by muse, mutect2, varscan2
- USP53 | c.2137A>G p.M713V | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99917799; called by muse, mutect2, varscan2
- XKR7 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs1457493681, COSV73813133; called by muse, mutect2, varscan2
- ZBBX | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100284248; called by muse, mutect2, varscan2
- ZNF677 | c.1714A>C p.K572Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV100447986; called by muse, mutect2
- A1CF | c.1252dup p.R418Kfs*7 (on ENST00000373993 / NM_138932.2; = p.R410Kfs*7 on NM_014576.4) | Frame Shift Ins (INS) | VAF 12/98 reads (12%) | called by mutect2, pindel, varscan2
- FAT2 | c.971_972del p.E324Vfs*48 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | called by mutect2, pindel, varscan2
- FSCN1 | c.319dup p.A107Gfs*44 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- KEAP1 | c.375dup p.E126* | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- LRP10 | c.1457dup p.I487Dfs*31 | Frame Shift Ins (INS) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- MTRES1 | c.97dup p.Y33Lfs*15 | Frame Shift Ins (INS) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.5787dup p.A1930Cfs*2 | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- NSD1 | c.5823dup p.P1942Sfs*4 | Frame Shift Ins (INS) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- PAPOLA | c.2143-7_2152del p.X715_splice | Splice Site (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel
- RARB | c.877_879del p.N293del (on ENST00000383772 / NM_001290216.2; = p.N286del on NM_000965.5 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel*, varscan2
- RIPK4 | c.1212_1221del p.S405Pfs*63 (on ENST00000352483; = p.S357Pfs*63 on NM_020639.3) | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- SHLD2 | c.1354dup p.C452Lfs*17 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- SLC38A4 | c.1033dup p.C345Lfs*4 | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- THAP9 | c.598dup p.Y200Lfs*2 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- A1BG | c.414G>A p.V138= | Silent (SNP) | VAF 53/267 reads (20%) | catalogued as COSV99568376; called by muse, mutect2, varscan2
- ABCA4 | c.3507A>G p.Q1169= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100933147; called by muse, mutect2
- ABCA6 | c.4023T>A p.A1341= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99446714; called by muse, mutect2
- BCCIP | c.24T>A p.R8= | Silent (SNP) | VAF 37/248 reads (15%) | catalogued as COSV53395822, COSV99533026; called by muse, mutect2, varscan2
- CEP112 | c.2229G>A p.Q743= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV101210793; called by muse, mutect2, varscan2
- CLYBL | c.745C>A p.R249= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs1217436926, COSV100185231, COSV59216798; called by muse, mutect2, varscan2
- CTNND2 | c.3354T>G p.T1118= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100477646; called by muse, mutect2, varscan2
- CYFIP1 | c.702C>T p.Y234= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as rs180812136; called by muse, mutect2, varscan2
- DHRS2 | c.573G>A p.A191= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs186440699, COSV99160857; called by muse, mutect2, varscan2
- EPB41L3 | c.600C>T p.I200= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100549446; called by muse, mutect2, varscan2
- FLNA | c.5034G>T p.A1678= (on ENST00000369850 / NM_001110556.2; = p.A1670= on NM_001456.3) | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV100774798, COSV61043165; called by muse, mutect2, varscan2
- GNA13 | c.852C>T p.V284= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV101457472; called by muse, mutect2, varscan2
- GPRIN3 | c.675A>G p.G225= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100310797; called by muse, mutect2, varscan2
- GRIN2A | c.702C>T p.D234= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs150208429, COSV100410082; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- H2BW1 | c.261G>A p.R87= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99475085; called by muse, mutect2, varscan2
- IGFBP6 | c.693C>T p.S231= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100037208; called by muse, mutect2, varscan2
- IRF2BP1 | c.417G>A p.G139= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100138909; called by muse, mutect2, varscan2
- KDM5C | c.3276A>G p.K1092= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1230365386, COSV100949247; ClinVar: likely benign; called by muse, mutect2, varscan2
- LGI1 | c.573C>A p.T191= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV101004428; called by muse, mutect2, varscan2
- MAP3K15 | c.3738C>T p.D1246= | Silent (SNP) | VAF 30/191 reads (16%) | catalogued as COSV100134910; called by muse, mutect2, varscan2
- NF1 | c.6201T>C p.P2067= (on ENST00000358273 / NM_001042492.3; = p.P2046= on NM_000267.3) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1555534671, COSV100647314; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT9 | c.585T>C p.H195= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100139247; called by muse, mutect2, varscan2
- OR6M1 | c.831G>T p.V277= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV100484093; called by muse, mutect2, varscan2
- PBXIP1 | c.1041G>A p.R347= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs1401716372, COSV100870096; called by muse, mutect2
- PLEKHA4 | c.2040G>A p.L680= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs142246074; called by muse, mutect2, varscan2
- PXDNL | c.2436C>T p.H812= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1453645611, COSV62491694; called by muse, mutect2
- REC8 | c.99C>T p.Y33= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs758743838, COSV100269088; called by muse, mutect2, varscan2
- RIPOR3 | c.2736G>T p.S912= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99246619; called by muse, mutect2, varscan2
- SAMSN1 | c.192C>T p.G64= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs764094326, COSV99581624; called by muse, varscan2
- SEL1L2 | c.1728A>G p.T576= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1335541480, COSV99533348; called by muse, mutect2, varscan2
- TBC1D3B | c.402G>A p.K134= | Silent (SNP) | VAF 70/339 reads (21%) | called by mutect2, varscan2
- XAB2 | c.957C>T p.R319= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV64321410; called by muse, mutect2, varscan2
- ZNF234 | c.1599T>C p.V533= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV101468375; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848967 T>C | 5'Flank (SNP) | VAF 9/40 reads (23%) | catalogued as rs1569512769; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 32/156 reads (21%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- DST | c.4297-2924A>G | Intron (SNP) | VAF 32/164 reads (20%) | catalogued as rs754617233, COSV99757166; called by muse, mutect2, varscan2
- EEF1B2 | c.398-178C>G | Intron (SNP) | VAF 11/68 reads (16%) | catalogued as rs767755310, COSV99261048; called by muse, mutect2, varscan2
- NACA | c.70+4535C>T | Intron (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100771390, COSV63268173; called by muse, mutect2, varscan2
- SNORD115-44 | n.1G>C | RNA (SNP) | VAF 72/370 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.7593C>A | RNA (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100022601; called by muse, varscan2
